Somatic mutation profile of tumor specimen BA2836D (aliquot aq-BA2836D) from BEATAML1.0 case 2242, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.2 years (21,615 days).
Specimen BA2836D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 305b61ae-29cd-4876-bd75-c1a2eccc362d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2509D (Solid Tissue Normal), aliquot aq-BA2509D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cba7213-7bba-43a0-be77-063277233c58

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT1 | c.8905G>A p.V2969I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as rs752874782; called by muse, mutect2, varscan2
- IFNA6 | c.209A>C p.Q70P | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV66507001; called by muse, mutect2, varscan2
- PLXNA2 | c.3627G>T p.Q1209H | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as rs1423685973; called by muse, mutect2
- TOMM40 | c.149C>A p.T50K | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.01); catalogued as rs1290415538; called by muse, mutect2
- FAM24A | c.268A>T p.S90C | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ANKRD9 | c.306G>T p.P102= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- PGAP1 | c.-1C>T | 5'UTR (SNP) | VAF 28/82 reads (34%) | catalogued as rs767741936; called by mutect2, varscan2
